Gene-level copy-number profile of tumor specimen C3N-03220-02 (profiled together with C3N-03220-03) from CPTAC case C3N-03220, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 86.2 years (31,488 days).
Specimen C3N-03220-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65501dd1-b652-4d7b-8888-bb9a18918053.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03220-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/e8c01af5-6848-4eb5-b094-f46336492961

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 5,909; copy number 2: 44,945; copy number 3: 6,947; copy number 4: 572.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:5,932,543–6,003,510, 2 genes: SILC1, MIR7158.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:64,439,346–64,765,535, 12 genes: SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:126,326,829–126,701,032, 9 genes: MVB12B, NRON, SNORD116, AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2.
- chr10:46,337,224–46,382,626, 3 genes (within-gene range 0–1): AGAP14P, FAM25BP, AC244230.1.
- chr10:87,863,625–87,994,695, 4 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
